Gene-level copy-number profile of tumor specimen ALCH-AES0-TTP1-A from ALCHEMIST case ALCH-AES0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.4 years (30,467 days).
Specimen ALCH-AES0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file effa4f34-65c3-4bfc-a9bc-c973f53c6b21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AES0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/869e5c2a-8874-46a2-aaad-1351b50b302e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 2,788; copy number 2: 54,818; copy number 3: 654; copy number 4: 44; copy number 5: 9; copy number 7: 2; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,046,828–109,090,858, 3 genes (within-gene range 0–2): RANP5, TAF13, AL356488.3.
- chr1:112,890,767–112,890,922, 1 gene: AL390729.1.
- chr2:91,578,478–91,659,972, 4 genes: AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr3:47,413,681–47,513,712, 4 genes: SCAP, AC099778.2, ELP6, BOLA2P2.
- chr4:40,423,267–40,630,875, 4 genes (within-gene range 0–1): RBM47, AC098869.2, AC098869.1, MIR4802.
- chr5:126,600,925–126,627,252, 1 gene: PHAX.
- chr6:73,241,314–73,310,365, 4 genes (within-gene range 0–2): KHDC1, AC019205.1, RPSAP41, EIF3EP1.
- chr6:73,413,515–73,525,587, 5 genes (within-gene range 0–1): CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1.
- chr6:107,133,071–107,133,170, 1 gene: RNU6-1299P.
- chr8:30,729,131–30,767,006, 2 genes: UBXN8, HIKESHIP3.
- chr8:54,130,582–54,148,514, 2 genes: Metazoa_SRP, MRPL15.
- chr9:6,639,139–6,639,604, 1 gene (within-gene range 0–2): RPL23AP57.
- chr9:33,817,160–33,920,399, 3 genes (within-gene range 0–3): UBE2R2, Y_RNA, RNU4ATAC11P.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr10:12,328,132–12,328,389, 1 gene: RN7SL198P.
- chr10:72,216,000–72,235,860, 2 genes (within-gene range 0–2): ANAPC16, Y_RNA.
- chr11:76,190,725–76,195,071, 1 gene (within-gene range 0–2): AP000785.1.
- chr12:114,737,704–114,737,798, 1 gene (within-gene range 0–2): AC026765.1.
- chr14:34,485,979–34,561,298, 7 genes (within-gene range 0–1): RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2.
- chr14:34,568,689–34,569,129, 1 gene (within-gene range 0–1): RPS19P3.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr15:22,773,063–22,829,789, 1 gene (within-gene range 0–1): NIPA1.
- chr18:12,050,309–12,050,672, 1 gene: AP001542.2.
- chr18:21,182,503–21,241,371, 2 genes: EXOGP1, AC022809.1.
- chr18:21,316,878–21,317,795, 1 gene (within-gene range 0–1): AC015878.2.
- chr20:346,782–359,660, 1 gene (within-gene range 0–1): NRSN2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr7:99,756,960–99,784,248, 2 genes, copy number 5: CYP3A4, AC069294.1.
- chr9:136,612,024–136,617,181, 1 gene, copy number 5: LINC01451.
- chr9:136,658,856–136,672,678, 2 genes, copy number 5 (within-gene range 3–5): EGFL7, MIR126.
- chr9:137,007,234–137,037,957, 3 genes, copy number 9 (within-gene range 4–9): ABCA2, C9orf139, FUT7.
- chr19:1,000,419–1,009,732, 1 gene, copy number 7 (within-gene range 3–7): GRIN3B.
- chr19:1,228,287–1,244,825, 3 genes, copy number 5 (within-gene range 3–5): CBARP, AC004221.1, ATP5F1D.
- chr19:1,397,026–1,401,570, 1 gene, copy number 7: GAMT.

Autosomal genes at a single copy (total copy number 1): 2,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
